TARGET case TARGET-15-SJMPAL042946 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3417f76a-85e6-407c-b510-7e3c4dcc715d

Demographics
Sex at birth: female; Age at index: 15 years; Vital status: Dead; Days to death: 320 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.3 years (5,588 days); Year of diagnosis: 2007; Days to last follow up: 320 days.

Follow-up (1 entry)
- Days to follow up: 320 days; Event-free: no event (relapse, second malignancy or death) recorded through day 320; Year of follow up: 2008.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 22.3 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL042946-04A, TARGET-15-SJMPAL042946-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Samples TARGET-15-SJMPAL042946-09A, TARGET-15-SJMPAL042946-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL042946-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 320
- Protocol: DCOG
- WBC at Diagnosis: 22.3
- Initial Therapy: ALL
- Karyotype: 47,XX,?inv(3)(q?12q26),+19[17]/46,XX[3]
- WHO ALAL Classification: NOS (T/B)
- WHO Dx: NOS (T/B)
- WHO RL1: NOS (T/B)
